TARGET case TARGET-40-0A4I4E — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/1c22d176-31f9-5228-b007-7be0c8328fae

Demographics
Sex at birth: male; Age at index: 16 years.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 16.4 years (5,978 days); Year of diagnosis: 2009; Metastasis at diagnosis: Metastasis, NOS; Sites of involvement: Lung, NOS.
   Treatment given: Protocol identifier: IHRT.

Biospecimens (2 samples)
- Sample TARGET-40-0A4I4E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I4E-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Proximal
- Primary site progression: No
